FM case AD4182 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adnexal and Skin Appendage Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/34bf7272-9cc9-400e-a1ad-862946e21037

Male, 68.2 years: Adnexal carcinoma (ICD-O-3 8390/3) of the skin; primary biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
